Somatic mutation profile of tumor specimen TCGA-76-4934-01A (aliquot TCGA-76-4934-01A-01D-1486-08) from TCGA case TCGA-76-4934, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 66.6 years (24,319 days).
Specimen TCGA-76-4934-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54fe7f9d-58e6-4142-a068-8028d83b3e00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-4934-10A (Blood Derived Normal), aliquot TCGA-76-4934-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/62738274-1ebe-463d-806f-f472c4d08293

The open-access MAF lists 55 somatic variants for this specimen: 44 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Nonsense Mutation 5, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 42/54 reads (78%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARSL | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745362620, COSV101140655, COSV66965140; called by muse, mutect2, varscan2
- ART4 | c.680C>T p.T227I | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs1038790098, COSV57451734; called by muse, mutect2, varscan2
- BATF | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54375737; called by muse, mutect2, varscan2
- BRD3 | c.721G>A p.G241S | Missense Mutation (SNP) | VAF 87/217 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV57703245; called by muse, mutect2, varscan2
- CAGE1 | c.1757C>T p.T586M (on ENST00000512086; = p.T450M on NM_205864.3) | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767515041, COSV57076781; called by muse, mutect2, varscan2
- CCDC85A | c.750G>C p.K250N | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.444); catalogued as COSV68150018; called by muse, mutect2, varscan2
- CFAP91 | c.1853G>A p.R618H | Missense Mutation (SNP) | VAF 85/158 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766630522, COSV56338804; called by muse, mutect2, varscan2
- COL1A2 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.084); catalogued as rs1016068209, COSV51956955; called by muse, mutect2, varscan2
- CSRNP1 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV56187890; called by muse, mutect2
- DCAF4L2 | c.154A>T p.S52C | Missense Mutation (SNP) | VAF 107/184 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV60478134; called by muse, mutect2, varscan2
- DTWD2 | c.8C>A p.S3* | Nonsense Mutation (SNP) | VAF 12/43 reads (28%) | catalogued as COSV58366206; called by muse, mutect2, varscan2
- FEZF1 | c.857G>A p.R286K | Missense Mutation (SNP) | VAF 91/221 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as COSV58658628; called by muse, mutect2, varscan2
- GUCY1A1 | c.1390C>T p.Q464* | Nonsense Mutation (SNP) | VAF 61/132 reads (46%) | catalogued as COSV56651157; called by muse, mutect2, varscan2
- HEATR3 | c.970G>C p.D324H | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV53529060; called by muse, mutect2, varscan2
- KDM5A | c.3571C>T p.L1191F | Missense Mutation (SNP) | VAF 49/312 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.102); catalogued as rs1359770831, COSV66991989; called by muse, mutect2, varscan2
- KIF4B | c.147C>G p.F49L | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70529031; called by muse, mutect2, varscan2
- LPAR3 | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 83/374 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.524); catalogued as rs767838020, COSV65453402; called by muse, mutect2, varscan2
- LYSMD3 | c.382C>G p.Q128E | Missense Mutation (SNP) | VAF 107/245 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV60057045; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1900G>A p.G634R | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376405101; called by muse, mutect2, varscan2
- NAF1 | c.1414C>T p.P472S | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.42); catalogued as COSV56804149; called by muse, mutect2, varscan2
- NALCN | c.3952C>T p.H1318Y | Missense Mutation (SNP) | VAF 132/212 reads (62%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV51931764; called by muse, mutect2, varscan2
- NDC80 | c.1751G>A p.R584H | Missense Mutation (SNP) | VAF 157/377 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs144795559; called by muse, mutect2, varscan2
- NEXN | c.1316G>T p.R439M | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57356817; called by muse, mutect2, varscan2
- OR4Q3 | c.368T>G p.L123W | Missense Mutation (SNP) | VAF 79/104 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100056683, COSV59177821; called by muse, mutect2, varscan2
- PCSK4 | c.1700C>T p.T567M | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs750452761, COSV56299056; called by muse, mutect2, varscan2
- POM121C | c.3647G>T p.R1216L (on ENST00000607367; = p.R974L on NM_001099415.3) | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV57545311; called by muse, mutect2, varscan2
- PRKAG3 | c.1079C>T p.A360V | Missense Mutation (SNP) | VAF 80/286 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV52101609; called by muse, mutect2, varscan2
- PSG11 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 185/488 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as rs925040845, COSV60454915, COSV60458274; called by muse, mutect2, varscan2
- PTEN | c.262T>C p.Y88H | Missense Mutation (SNP) | VAF 100/127 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as CM032997, COSV64292718, COSV64295467; called by muse, mutect2, varscan2
- RADX | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 83/341 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV65317787, COSV65319445; called by muse, mutect2, varscan2
- SLC6A3 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs376877303; called by muse, mutect2, varscan2
- STARD8 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 65/125 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs200556349, COSV52925468; called by muse, mutect2, varscan2
- STK10 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 101/139 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs550965424, COSV51573533; called by muse, mutect2, varscan2
- STON1 | c.1331G>T p.C444F | Missense Mutation (SNP) | VAF 200/383 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV59129594; called by muse, mutect2, varscan2
- TJAP1 | c.1042C>T p.P348S (on ENST00000372445 / NM_001146016.1; = p.P338S on NM_080604.3) | Missense Mutation (SNP) | VAF 69/200 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52500630; called by muse, mutect2, varscan2
- TNFRSF1A | c.368C>A p.T123N | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50599826; called by muse, mutect2, varscan2
- TPTE2 | c.529C>T p.R177* (on ENST00000400230 / NM_199254.2; = p.R100* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 19/73 reads (26%) | catalogued as rs538397448, COSV55016766, COSV55028827; called by muse, mutect2, varscan2
- ZC3H18 | c.1561C>T p.R521* | Nonsense Mutation (SNP) | VAF 41/76 reads (54%) | catalogued as COSV56324235, COSV99964491; called by muse, mutect2, varscan2
- ZDBF2 | c.3770C>A p.P1257H | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV65624964; called by muse, mutect2, varscan2
- ZNF280C | c.1462C>T p.H488Y | Missense Mutation (SNP) | VAF 156/359 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63968826; called by muse, mutect2, varscan2
- ZNF595 | c.1562C>G p.S521* | Nonsense Mutation (SNP) | VAF 43/181 reads (24%) | catalogued as COSV59546736; called by muse, mutect2, varscan2
- GPATCH1 | c.148del p.H50Tfs*56 | Frame Shift Del (DEL) | VAF 68/187 reads (36%) | called by mutect2, pindel, varscan2
- IGBP1P2 | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- CD40 | c.249C>T p.C83= | Silent (SNP) | VAF 42/179 reads (23%) | catalogued as rs776893342, COSV64847704; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERICH6 | c.1377G>A p.V459= | Silent (SNP) | VAF 146/344 reads (42%) | catalogued as COSV55800073; called by muse, mutect2, varscan2
- FGL1 | c.600C>T p.Y200= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as rs142240316; called by muse, mutect2, varscan2
- GLI2 | c.696G>A p.A232= | Silent (SNP) | VAF 114/228 reads (50%) | catalogued as rs749583415, COSV58040305; called by muse, mutect2, varscan2
- KIT | c.132A>G p.S44= | Silent (SNP) | VAF 3285/3401 reads (97%) | catalogued as COSV55397778, COSV99854307; called by muse, mutect2, varscan2
- KRT73 | c.435C>T p.S145= | Silent (SNP) | VAF 98/251 reads (39%) | catalogued as COSV59838927; called by muse, mutect2, varscan2
- LRIG3 | c.1632T>C p.A544= | Silent (SNP) | VAF 90/222 reads (41%) | catalogued as COSV57862900; called by muse, mutect2, varscan2
- PASK | c.2550G>A p.T850= | Silent (SNP) | VAF 159/293 reads (54%) | catalogued as rs764571398, COSV52151594; called by muse, mutect2, varscan2
- SLC39A12 | c.1227C>T p.V409= | Silent (SNP) | VAF 141/193 reads (73%) | catalogued as rs201107118, COSV66197561; called by muse, mutect2, varscan2
- TRBV4-1 | c.42G>T p.L14= | Silent (SNP) | VAF 36/172 reads (21%) | called by muse, mutect2, varscan2
- COL6A2 | c.2462-2480G>A | Intron (SNP) | VAF 18/39 reads (46%) | catalogued as rs138231613; called by muse, mutect2, varscan2
